CCDI case PBCPAJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a05da415-b8c6-4786-9633-45203685f9fd

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 20.2 years (7,378 days).

Biospecimens (3 samples)
- Sample 0DWKG0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWKGW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWKH1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
